Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6825, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6825-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: M

Material: **Lesion resection – tumour of the tongue, right side**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **tumour of the tongue, right side**

Examination performed on:

Macroscopic description:

A fragment of the tongue sized 6.5 x 4.2 x 3 with a tumour sized 2.5 x 2.2 x 1 cm. In addition, a surgical specimen sized 1.5 x 1.7 x 1.2, beige in cross section.

Microscopic description:

Carcinoma planoepitheliale keratodes invasivum G2.

Minimum margin of healthy tissues from the side surface of the surgical specimen: 0.4 cm.

Minimum margin of healthy tissues from the base of the surgical specimen: 0.5 cm.

Reactio lymphocytaria peritumoralis.

Ponadto fragment ślinianki bez nacieku nowotworowego.

Histopathological Diagnosis:

Carcinoma planoepitheliale keratodes invasivum linguae. Invasive squamous keratinized carcinoma of the tongue. G2, pTl.

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file c1f73a3e-faf0-4ad0-8eb7-99de24fa13f4 (TCGA-D6-6825.FBBEEAE7-CD3F-481E-B093-3B5518155E88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).